Gene-level copy-number profile of tumor specimen TCGA-EB-A553-01A from TCGA case TCGA-EB-A553, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 62.9 years (22,972 days).
Specimen TCGA-EB-A553-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.7eba0a7f-d2bd-442c-8327-68997cc2dc7a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A553-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5df2eb63-75f6-478c-b77c-3129e62d29be

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2,054; copy number 2: 28,681; copy number 3: 21,378; copy number 4: 5,736; copy number 5: 1,416; copy number 6: 549.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A553-01A-12D-A27J-01): tumor purity 0.58, ploidy 2.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,265,145, 3 genes (within-gene range 0–1): LINC00290, AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,965 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:35,614,650–35,734,924, 4 genes, copy number 5 (within-gene range 4–5): AC018647.3, HERPUD2, AC018647.2, AC018647.1.
- chr7:92,971,002–159,233,377, 1,372 genes, copy number 5–6 (broad region; genes not listed).
- chr20:41,098,019–64,313,132, 589 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,690. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
